Somatic mutation profile of tumor specimen TCGA-A2-A0CQ-01A (aliquot TCGA-A2-A0CQ-01A-21W-A050-09) from TCGA case TCGA-A2-A0CQ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 62.5 years (22,810 days).
Specimen TCGA-A2-A0CQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89dca2d6-6701-425c-84bd-71a3d3d2fcec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0CQ-10A (Blood Derived Normal), aliquot TCGA-A2-A0CQ-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3ef1431-fcf5-4dd3-a264-58df2c96321c

The open-access MAF lists 37 somatic variants for this specimen: 25 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 24, Silent 12, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFF2 | c.952C>A p.L318M | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.897); catalogued as COSV60671630; called by muse, mutect2, varscan2
- AKAP11 | c.2686G>A p.V896I | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV50298383; called by muse, mutect2, varscan2
- CLTCL1 | c.2966C>T p.S989L | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781858778, COSV54227380; called by muse, mutect2, varscan2
- COL27A1 | c.1946G>A p.G649D | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs981318664, COSV100620925; called by muse, mutect2
- CTCF | c.1132C>G p.P378A | Missense Mutation (SNP) | VAF 101/142 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50479935; called by muse, mutect2, varscan2
- DOCK10 | c.1277G>A p.S426N | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as COSV51420093; called by muse, mutect2, varscan2
- FPGS | c.365G>A p.G122D | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1170943148, COSV64676307; called by muse, mutect2
- GRHL2 | c.1627A>T p.R543W | Missense Mutation (SNP) | VAF 85/197 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52550952; called by muse, mutect2, varscan2
- IQCG | c.1121T>C p.I374T | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs374289605; called by muse, mutect2, varscan2
- KCTD7 | c.335G>T p.R112L | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51877044, COSV99299062; called by muse, mutect2, varscan2
- KIAA1210 | c.1139C>T p.T380I | Missense Mutation (SNP) | VAF 52/522 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV101274068; called by muse, mutect2
- MACF1 | c.14832G>C p.E4944D (on ENST00000372915; = p.E2877D on NM_012090.5) | Missense Mutation (SNP) | VAF 8/65 reads (12%) | catalogued as COSV57130133; called by muse, mutect2, varscan2
- NDNF | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs994851514, COSV101113219, COSV65634061; called by muse, mutect2, varscan2
- NEK8 | c.1910G>C p.W637S | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52046374; called by muse, mutect2, varscan2
- PDIK1L | c.425C>A p.T142N | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as COSV100957677, COSV65322940; called by muse, mutect2
- PIK3R1 | c.1375_1386dup p.K459_E462dup (on ENST00000521381 / NM_181523.3; = p.K189_E192dup on NM_181504.4) | In Frame Ins (INS) | VAF 7/31 reads (23%) | catalogued as COSV57134253; called by mutect2, varscan2
- PTCHD1 | c.373A>T p.I125F | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as COSV65061530; called by muse, mutect2, varscan2
- SLC36A4 | c.450G>C p.W150C | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100419331; called by muse, mutect2
- SNX29 | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as COSV60054957; called by muse, mutect2
- STARD7 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 28/205 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs149097861; called by muse, mutect2, varscan2
- TRIP11 | c.187A>G p.I63V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs766430885, COSV50935028; called by muse, mutect2, varscan2
- TSPAN33 | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.072); catalogued as rs768190545, COSV56825609; called by muse, mutect2
- UPF1 | c.1319C>T p.T440M (on ENST00000599848 / NM_001297549.2; = p.T429M on NM_002911.4) | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs1361149765, COSV53197168; called by muse, mutect2, varscan2
- VAMP5 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.013); catalogued as rs769759669, COSV60498396; called by muse, mutect2, varscan2
- ZNF578 | c.967T>A p.S323T | Missense Mutation (SNP) | VAF 70/196 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV69736949; called by muse, mutect2, varscan2
- BOC | c.3294C>T p.S1098= | Silent (SNP) | VAF 33/87 reads (38%) | catalogued as COSV56354027; called by muse, mutect2, varscan2
- CACNA1C | c.6231C>T p.S2077= (on ENST00000399634 / NM_001167625.1; = p.S2006= on NM_000719.7) | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs368817423; called by muse, mutect2, varscan2
- DIP2C | c.4581C>T p.I1527= | Silent (SNP) | VAF 41/145 reads (28%) | catalogued as COSV55166139; called by muse, mutect2, varscan2
- DNAH2 | c.870C>T p.G290= | Silent (SNP) | VAF 11/217 reads (5%) | catalogued as COSV99318116; called by muse, mutect2
- GBA2 | c.1791C>T p.D597= | Silent (SNP) | VAF 27/408 reads (7%) | catalogued as COSV100803368; called by muse, mutect2
- IPPK | c.1230T>C p.S410= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV55334641; called by muse, mutect2, varscan2
- MEPCE | c.774T>A p.T258= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV52769466; called by muse, mutect2, varscan2
- MFSD11 | c.1152C>T p.S384= | Silent (SNP) | VAF 66/176 reads (38%) | catalogued as rs758718846, COSV60625690; called by muse, mutect2, varscan2
- MRPL40 | c.33A>G p.L11= | Silent (SNP) | VAF 10/12 reads (83%) | catalogued as rs999982880; called by muse, varscan2
- OR6C2 | c.921A>G p.A307= | Silent (SNP) | VAF 81/209 reads (39%) | catalogued as COSV59516411; called by muse, mutect2, varscan2
- SLC9A1 | c.1008C>G p.L336= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV56054700; called by muse, mutect2, varscan2
- SLC9C2 | c.987C>T p.H329= | Silent (SNP) | VAF 25/102 reads (25%) | catalogued as rs201172272, COSV62946879; called by muse, mutect2, varscan2
